Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4T8, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4T8-01A (Primary Tumor).

Surgical Pathology

Requested By:

TISSUE DESCRIPTION:

A1 B1 C1 C2 C3 C4 C5 C6 D1 D2 E1 F1
Left upper lobe lung (185.0 grams, 17.0 x 10.0 x 3.0 cm), station 5L, 6L, 7, 9L, and 11L lymph nodes.

DIAGNOSIS:

Lung, left upper lobe, lobectomy: Grade 3 (of 4) adenocarcinoma forming a bronchocentric mass (4.5 x 3.0 x 1.5 cm) not involving the pleura. Angiolymphatic invasion is identified. The bronchial margin is free of tumor.

Lymph nodes, mediastinal, excision:

- Metastatic grade 3 (of 4) adenocarcinoma is identified in a single left subaortic (station 5L) lymph node.
- No tumor is identified in a single left paraaortic (station 6L) lymph node.
- No tumor is identified in multiple (3) subcarinal (station 7) lymph nodes.
- No tumor is identified in a single left pulmonary ligament (station 9L) lymph node.

Lymph nodes, intrapulmonary/hilar, excision:

- Metastatic grade 3 (of 4) adenocarcinoma is identified in multiple (2 of 6) intrapulmonary peribronchial lymph nodes.
- No tumor is identified in a single left interlobar (station 11L) lymph node.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: lung, upper lobe C34.1

hw
10/27/12

Source: NCI Genomic Data Commons file 475049d3-4e88-4838-831a-31480546c1cc (TCGA-MP-A4T8.11D12F13-E03D-43D1-B0B1-AD9168960EE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).